CPTAC case C3L-01889 — Bronchus and lung — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5d66be2e-e3a3-460d-ac80-0ac8112ba9c6

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1945; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Upper lobe, lung; Age at diagnosis: 71.7 years (26,205 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T2a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IB; Tumor grade: G2; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 1,799 days (4.9 years); Progression or recurrence: no; Days to last follow up: 1,799 days (4.9 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 2.2 cm (a second GDC size field records 3.5 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 12; Margin status: Uninvolved.

Follow-up (6 entries)
- Days to follow up: 364 days; Disease response: Tumor Free.
- Days to follow up: 686 days (1.9 years); Disease response: Tumor Free.
- Days to follow up: 1,071 days (2.9 years); Disease response: Tumor Free.
- Days to follow up: 1,355 days (3.7 years); Disease response: Tumor Free.
- Days to follow up: 1,355 days (3.7 years); Disease response: Complete Response.
- Days to follow up: 1,799 days (4.9 years); Disease response: Tumor Free.

Other clinical attributes
- Weight: 97.7 kg; Height: 167 cm; BMI: 35.03; DLCO (% of predicted): 67; FEV1/FVC after bronchodilator (%): 69; FEV1/FVC before bronchodilator (%): 68; FEV1 after bronchodilator (% of reference): 73; FEV1 before bronchodilator (% of reference): 76.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 60; Cigarettes per day: 30; Tobacco smoking onset year: 1959; Tobacco smoking quit year: 1999; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker; Exposure duration years: 40.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-01889-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 282 mg; Time between excision and freezing: 13 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-01889-21: Section location: Right Upper Lobe; Percent tumor nuclei: 80; Percent necrosis: 0.
- Sample C3L-01889-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 508 mg; Time between excision and freezing: 13 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-01889-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
